Somatic mutation profile of tumor specimen MP2PRT-PARKKC-TMP1-A (aliquot MP2PRT-PARKKC-TMP1-A-1-0-D-A834-36) from MP2PRT case MP2PRT-PARKKC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.3 years (3,408 days).
Specimen MP2PRT-PARKKC-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e07a50a0-0a8f-4dbf-b9f1-aaeee39cf907.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARKKC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARKKC-NB1-A-1-0-D-A834-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/26a88ad3-7f5b-463b-b663-e6ece64c3313

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 10, Silent 4, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CXCR4 | c.1000C>T p.R334* | Nonsense Mutation (SNP) | VAF 107/269 reads (40%) | catalogued as rs104893624, CM030831, COSV54010080; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 157/389 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARHGEF10L | c.1094G>A p.R365H | Missense Mutation (SNP) | VAF 214/447 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51430321; called by muse, mutect2, varscan2
- CDS1 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 80/284 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs530030554; called by muse, mutect2, varscan2
- CEP128 | c.1780G>A p.E594K | Missense Mutation (SNP) | VAF 141/501 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1460947744, COSV55367965, COSV55388896; called by muse, mutect2, varscan2
- DCDC1 | c.1660C>T p.R554W | Missense Mutation (SNP) | VAF 153/342 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs573626854; called by muse, mutect2, varscan2
- GRIN2A | c.3505C>T p.R1169W | Missense Mutation (SNP) | VAF 197/394 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs369878342, COSV58036726, COSV58048965; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- TLE3 | c.493G>A p.G165R | Missense Mutation (SNP) | VAF 261/576 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as rs1286617949, COSV100450038; called by muse, mutect2, varscan2
- TTN | c.97903C>T p.R32635W (on ENST00000591111; = p.R25211W on NM_003319.4) | Missense Mutation (SNP) | VAF 154/323 reads (48%) | PolyPhen probably damaging (0.973); catalogued as rs781432886, COSV60278748; called by muse, mutect2, varscan2
- USP6 | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 151/540 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); catalogued as rs114647990, COSV51473183; called by muse, mutect2, varscan2
- WDR38 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 174/416 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs564239252; called by muse, mutect2, varscan2
- KRT36 | c.270C>T p.N90= | Silent (SNP) | VAF 201/599 reads (34%) | catalogued as rs188302666, COSV60203621; called by muse, mutect2, varscan2
- MYLK | c.1314C>T p.S438= | Silent (SNP) | VAF 20/250 reads (8%) | catalogued as rs200423954, COSV60609683; ClinVar: likely benign; called by muse, mutect2
- SHARPIN | c.792G>A p.P264= | Silent (SNP) | VAF 231/763 reads (30%) | catalogued as rs370921402; called by muse, mutect2, varscan2
- SORBS2 | c.1206G>A p.S402= | Silent (SNP) | VAF 158/582 reads (27%) | catalogued as rs751314536; called by muse, mutect2, varscan2
